Somatic mutation profile of tumor specimen C3N-01175-01 (aliquot CPT0078660009) from CPTAC case C3N-01175, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 60.8 years (22,205 days).
Specimen C3N-01175-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8a798262-cb20-4cd1-adc0-a0f1914dd677.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01175-31 (Blood Derived Normal), aliquot CPT0078700002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b9050dcc-a21a-4325-ab6c-ced48da82f44

The open-access MAF lists 13 somatic variants for this specimen: 7 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 5, In Frame Del 1, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.916C>T p.R306* | Nonsense Mutation (SNP) | VAF 308/554 reads (56%) | hotspot (GDC flag); catalogued as rs121913344, CM971506, COSV52662281, COSV52987117, COSV53852813; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AHNAK | c.6554C>T p.S2185F | Missense Mutation (SNP) | VAF 191/551 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99946938; called by muse, mutect2, varscan2
- FGD2 | c.995G>A p.R332H | Missense Mutation (SNP) | VAF 65/111 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777342221, COSV99236129; called by muse, mutect2, varscan2
- NAV3 | c.2293C>T p.R765C | Missense Mutation (SNP) | VAF 83/264 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as rs572701178, COSV57061979; called by muse, mutect2, varscan2
- ANKIB1 | c.2367C>G p.D789E | Missense Mutation (SNP) | VAF 12/218 reads (6%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.011); called by muse, mutect2
- BBX | c.1353_1355del p.K456del | In Frame Del (DEL) | VAF 60/189 reads (32%) | called by mutect2, pindel, varscan2
- SUPT5H | c.3058G>A p.E1020K | Missense Mutation (SNP) | VAF 15/225 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.021); called by muse, mutect2
- COL15A1 | c.1758C>T p.P586= | Silent (SNP) | VAF 65/215 reads (30%) | catalogued as COSV100897674; called by muse, mutect2, varscan2
- LRRC74A | c.156G>A p.P52= | Silent (SNP) | VAF 69/169 reads (41%) | catalogued as rs568264390, COSV53611071; called by muse, mutect2, varscan2
- PTPRB | c.5136C>T p.D1712= | Silent (SNP) | VAF 37/291 reads (13%) | catalogued as rs1305673646; called by muse, mutect2, varscan2
- RBFOX3 | c.480G>A p.G160= | Silent (SNP) | VAF 63/132 reads (48%) | called by muse, mutect2, varscan2
- TULP4 | c.1443G>A p.R481= | Silent (SNP) | VAF 123/246 reads (50%) | called by muse, mutect2, varscan2
- ASAH1 | c.1146+46T>C | Intron (SNP) | VAF 14/148 reads (9%) | called by muse, mutect2
